Gene-level copy-number profile of tumor specimen TCGA-AF-2691-01A from TCGA case TCGA-AF-2691, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 48.6 years (17,759 days).
Specimen TCGA-AF-2691-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.efba93c7-9010-4ebc-8598-8b42eb47c214.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AF-2691-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32fd263c-3aea-4af2-b539-4ee06a4a7369

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 20,394; copy number 2: 35,535; copy number 3: 1,605; copy number 4: 1,391; copy number 5: 886.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AF-2691-01A-01D-1549-01): tumor purity 0.43, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:88,113,251–89,065,945, 9 genes (within-gene range 0–1): RAB38, AP001642.1, MIR3166, CTSC, GAPDHP70, AP003120.1, GRM5-AS1, GRM5, RNU6-16P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 886 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:31,257,664–64,313,132, 886 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20,394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
